Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABJP, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABJP-TTP1-B (Primary Tumor).

Material description

- A. Lung
- B. Lymph node
- C. Lymph node

CDDP-YP-ABJP-01-PR

Macro description

A. Right upper lung, lobectomy. Lobe weight 230 grams and lobe size 18 x 10 x 4 cm.

In the para hilar area we observe whitish neoformation: soft consistence, dimension 4 cm, far from the visceral pleura 1,5 cm

The remaining parenchyma seems solid, not ventilated.

Samples:

- A) neoformation
- B) margin of bronchial resection
- C) parenchyma at distance
- D) bronchial wall

ICD-0-3

adenocarcinoma, NOS 8140/3
Site: (R) lung, upper lobe C34.1

ICD-10

C34.11

B. Lymph nodes n.1: 3 blackish fragments

C. Lymph nodes n.2 : 7 blackish fragments maximum 0.8 cm

hw
2/9/16

Micro description

A. ABCD) Adenocarcinoma GIII. Bronchial margin and parenchyma at distance unscathed from neoplastic infiltration

B. Reactive lymphadenitis on 3 examined lymph nodes

C. Reactive lymphadenitis on 7 examined lymph nodes

Staging TNM:

T2,NO,Mx,G3

Hist. Axi. Discrepancy		☒

Source: NCI Genomic Data Commons file ec88ef05-0efb-44ba-92d2-f00bb02cd79f (CDDP-ABJP-TTP1.DFCB1012-2193-496C-B782-BA41CA3DC53E.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).